Somatic mutation profile of tumor specimen TCGA-19-5951-01A (aliquot TCGA-19-5951-01A-11D-1696-08) from TCGA case TCGA-19-5951, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.6 years (27,995 days).
Specimen TCGA-19-5951-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dc1aa55-2223-4078-9a44-cad67fb47151.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-5951-10A (Blood Derived Normal), aliquot TCGA-19-5951-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fca0a4d1-d666-415e-9aed-315be5b0f5da

The open-access MAF lists 78 somatic variants for this specimen: 57 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, RNA 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1188_1202del p.T397_V401del (on ENST00000521381 / NM_181523.3; = p.T127_V131del on NM_181504.4) | In Frame Del (DEL) | VAF 20/89 reads (22%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCC9 | c.3284G>A p.R1095H | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs869025347, COSV53970017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSM4 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs772162110, COSV68067615; called by muse, mutect2, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | catalogued as rs570442888; called by mutect2, varscan2
- ADCY8 | c.2087A>C p.K696T | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV53905884, COSV53920322; called by muse, mutect2, varscan2
- AK7 | c.210A>T p.K70N | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV50871111; called by muse, mutect2, varscan2
- AMOT | c.2219G>T p.R740L (on ENST00000371959 / NM_001113490.1; = p.R331L on NM_133265.3) | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV59063052; called by muse, mutect2, varscan2
- APOBR | c.1550C>T p.A517V (on ENST00000431282; = p.A526V on NM_018690.4) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV60490274; called by muse, mutect2
- BRF2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746089287, COSV55103373; called by muse, mutect2, varscan2
- BSN | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs376181418, COSV56517028; called by muse, mutect2, varscan2
- C5AR1 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs866029894, COSV61892408, COSV61892521; called by muse, mutect2, varscan2
- CD36 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.672); catalogued as rs775941131, COSV59212657; called by muse, mutect2, varscan2
- CD3E | c.283T>C p.Y95H | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV62345692; called by muse, mutect2, varscan2
- CLEC14A | c.972C>A p.D324E | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.013); catalogued as COSV100643602, COSV60562405; called by muse, mutect2, varscan2
- COL15A1 | c.2776C>A p.P926T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV66644119; called by muse, mutect2, varscan2
- COL6A3 | c.5149G>A p.A1717T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs376135795, COSV55088006; called by muse, mutect2, varscan2
- DNAH5 | c.12380G>A p.R4127H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762555871, COSV54221607; called by muse, mutect2, varscan2
- DNALI1 | c.436C>T p.R146C (on ENST00000296218; = p.R124C on NM_003462.5) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375269116; called by muse, mutect2, varscan2
- DSP | c.7169T>C p.I2390T | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs779025714, COSV65792489; called by muse, mutect2, varscan2
- ELK1 | c.1205G>A p.S402N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs770813034, COSV55952760; called by muse, mutect2, varscan2
- ERCC6L | c.2960A>G p.N987S | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV57820441; called by muse, mutect2, varscan2
- FAT4 | c.3803C>T p.T1268I | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV67885529; called by muse, mutect2, varscan2
- FOXL1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.777); catalogued as COSV57214173, COSV57214290; called by muse, mutect2, varscan2
- GDI1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV63895626; called by muse, mutect2, varscan2
- GDNF | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58479267; called by muse, mutect2, varscan2
- GPR146 | c.957del p.H320Tfs*24 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs775654196; called by mutect2, pindel, varscan2
- INPP4B | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs763155133, COSV53722964; called by muse, mutect2, varscan2
- JAG2 | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs200736888; called by muse, mutect2, varscan2
- KIF17 | c.2363C>T p.S788L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs370565385, COSV56122398; called by muse, mutect2, varscan2
- KIF24 | c.1708C>T p.R570* | Nonsense Mutation (SNP) | VAF 173/188 reads (92%) | catalogued as rs764804578, COSV61454674; called by muse, mutect2, varscan2
- LCE3A | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV59550578; called by muse, mutect2, varscan2
- LEFTY2 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs746371252, COSV64746827; called by muse, mutect2, varscan2
- LRRK1 | c.4270G>A p.V1424M | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as rs767219901, COSV52609803; called by muse, mutect2, varscan2
- NOBOX | c.690C>A p.H230Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV56194075; called by muse, mutect2, varscan2
- OR2T1 | c.467T>C p.F156S | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs373134110; called by muse, mutect2, varscan2
- OR51A7 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV63788284; called by muse, mutect2, varscan2
- OR52B6 | c.527T>A p.F176Y | Missense Mutation (SNP) | VAF 109/247 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV61447761; called by muse, mutect2, varscan2
- PCDHA6 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.214); catalogued as rs1202815393, COSV67050451; called by muse, varscan2
- PCDHGA4 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV53938487; called by muse, mutect2, varscan2
- PDE1C | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 100/243 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs558149608, COSV58512520; called by muse, mutect2, varscan2
- PLXNA1 | c.2723G>A p.S908N | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs138171477; called by muse, mutect2, varscan2
- POU2AF1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67577201; called by muse, mutect2, varscan2
- PPARGC1B | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs182592244; called by muse, mutect2, varscan2
- RNF17 | c.4433C>T p.T1478M | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764724343, COSV55039381; called by muse, mutect2, varscan2
- SHROOM4 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs376491533, COSV56788627; called by muse, mutect2, varscan2
- SLC26A4 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs779745819, CM1111378, COSV55916347; called by muse, mutect2, varscan2
- SLCO1B3 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.764); catalogued as rs778801571, COSV53936821; called by muse, mutect2, varscan2
- SOX17 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs931390946, COSV52024391; called by muse, mutect2
- TBC1D31 | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54865782; called by muse, mutect2, varscan2
- TIE1 | c.2995G>T p.G999C | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65249548; called by muse, mutect2
- TMEM255A | c.612C>A p.Y204* | Nonsense Mutation (SNP) | VAF 85/185 reads (46%) | catalogued as COSV59028174, COSV59029063; called by muse, mutect2, varscan2
- TRIO | c.5608C>G p.P1870A | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60082883; called by muse, mutect2, varscan2
- WAS | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV64996982; called by muse, mutect2, varscan2
- ZNF676 | c.456C>G p.N152K (on ENST00000650058; = p.N120K on NM_001001411.3) | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68092958; called by muse, mutect2, varscan2
- CCDC148 | c.93dup p.L32Ifs*6 | Frame Shift Ins (INS) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PIF1 | c.1528+1del p.X510_splice | Splice Site (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- ADGRE1 | c.984C>T p.P328= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs748327859, COSV51674380; called by muse, mutect2, varscan2
- AL592490.1 | c.2598G>A p.E866= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV69426046; called by muse, mutect2, varscan2
- ARSH | c.291G>A p.T97= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as rs745786885, COSV66962888; called by muse, mutect2, varscan2
- CACNB3 | c.411A>G p.R137= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV56398098; called by muse, mutect2, varscan2
- DOCK5 | c.4260G>A p.S1420= | Silent (SNP) | VAF 68/139 reads (49%) | catalogued as rs566691068, COSV52400623; called by muse, mutect2, varscan2
- DSCAM | c.4173G>A p.T1391= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs765940317, COSV68025912; called by muse, mutect2, varscan2
- HMCN1 | c.8472A>G p.V2824= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV54897138; called by muse, mutect2, varscan2
- HRNR | c.7155T>C p.S2385= | Silent (SNP) | VAF 53/492 reads (11%) | catalogued as COSV100913331; called by mutect2, varscan2
- NCOA3 | c.1776C>T p.H592= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV59068202; called by muse, mutect2, varscan2
- NRN1 | c.261G>A p.A87= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV55205450, COSV99784311; called by muse, mutect2, varscan2
- NSG1 | c.267C>T p.F89= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as rs143847165; called by muse, mutect2, varscan2
- OR2F2 | c.228C>T p.S76= | Silent (SNP) | VAF 104/243 reads (43%) | catalogued as rs377643542; called by muse, mutect2, varscan2
- OR4K17 | c.498G>A p.L166= | Silent (SNP) | VAF 101/220 reads (46%) | catalogued as COSV59647952; called by muse, mutect2, varscan2
- RAVER1 | c.765C>T p.C255= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as rs751621218, COSV53345166; called by muse, mutect2, varscan2
- RBM4 | c.957C>T p.P319= | Silent (SNP) | VAF 47/112 reads (42%) | catalogued as rs777485002, COSV59518701; called by muse, mutect2, varscan2
- SEMA3G | c.804C>T p.R268= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs138050174; called by muse, mutect2, varscan2
- SLC5A2 | c.1629G>A p.T543= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs779189173, COSV57891243; called by muse, mutect2, varscan2
- SNX5 | c.840G>A p.E280= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as COSV66697887; called by muse, mutect2, varscan2
- ZNF182 | c.78A>G p.L26= | Silent (SNP) | VAF 72/148 reads (49%) | catalogued as COSV59357058; called by muse, mutect2, varscan2
- MFRP | chr11:119344953 G>A | 5'Flank (SNP) | VAF 8/19 reads (42%) | catalogued as COSV64128037, COSV64128306; called by muse, mutect2, varscan2
- MIR124-1 | n.55A>T | RNA (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
